Somatic mutation profile of tumor specimen 0DTC61 from CCDI case PBCJMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,771 days).
Specimen 0DTC61: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3b33a14-0e78-419c-afcc-610a82a37066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cba26dfd-30af-4234-bb05-11f59b9962b7

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F13B | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2Y1 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- WDFY4 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 20/409 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2
